TCGA case TCGA-CJ-4868 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2309c424-26fa-4cc6-a22a-2dc0f989af59

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 42 years; Vital status: Dead; Days to death: 646 days (1.8 years).

Diagnoses (2)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 42.7 years (15,601 days); Year of diagnosis: 2005; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 14.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Aldesleukin; Initial disease status: Progressive Disease; Days to treatment start: 56 days; Days to treatment end: 89 days; Number of cycles: 2; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 109 days; Days to treatment end: 126 days; Treatment dose: 3,500 cGy; Course number: 1; Number of fractions: 14; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Erlotinib Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 114 days; Days to treatment end: 288 days; Number of cycles: 10; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 135 days; Days to treatment end: 282 days; Number of cycles: 10; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Initial disease status: Recurrent Disease; Days to treatment start: 183 days; Days to treatment end: 188 days; Treatment dose: 2,700 cGy; Course number: 2; Number of fractions: 3; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Initial disease status: Progressive Disease; Days to treatment start: 296 days; Days to treatment end: 365 days (1.0 years); Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 296 days; Days to treatment end: 365 days (1.0 years); Number of cycles: 3; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sorafenib Tosylate; Initial disease status: Progressive Disease; Days to treatment start: 379 days (1.0 years); Days to treatment end: 534 days (1.5 years); Number of cycles: 1; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Initial disease status: Recurrent Disease; Days to treatment start: 505 days (1.4 years); Days to treatment end: 505 days (1.4 years); Treatment dose: 2,000 cGy; Course number: 3; Number of fractions: 1; Treatment anatomic sites: Distant Site.
2. Metastasis of diagnosis 1 (Clear cell adenocarcinoma, NOS). Age at diagnosis: 42.8 years (15,638 days); Days to diagnosis: 37 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 456 days (1.2 years); Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Locoregional Site.

Follow-up (4 entries)
- Day 37 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 37 days.
- Days to follow up: 646 days (1.8 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Recurrence/Progression.
- ECOG performance status: 0; Timepoint: Preoperative.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CJ-4868-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 3; Intermediate dimension: 0.8; Shortest dimension: 0.6.
  Slide TCGA-CJ-4868-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25.
  Slide TCGA-CJ-4868-01A-01-TS1: Section location: Top; Percent tumor cells: 68; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 30.
- Sample TCGA-CJ-4868-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CJ-4868-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 3.5; Intermediate dimension: 0.9; Shortest dimension: 0.9.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Proleukin; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 4; Pharmaceutical therapy drug name: Nexavar; Therapy regimen: Progression.
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Drug treatment 3: Regimen number: 3; Therapy regimen: Progression.
- Drug treatment 4: Regimen number: 2; Pharmaceutical therapy drug name: Avastin; Therapy regimen: Progression.
- Drug treatment 5: Regimen number: 3; Pharmaceutical therapy drug name: Capecitabin; Therapy regimen: Progression.
- Drug treatment 6: Pharmaceutical therapy drug name: Tarceva; Therapy regimen: Progression.
- Radiation treatment 2: Radiation type other: Stereotactic radiotherapy; Therapy regimen: Recurrence.
- Radiation treatment 3: Radiation type other: Stereotactic radiosurgery; Therapy regimen: Recurrence.
- Follow-up form: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: Yes; Performance status timing: At Recurrence/Progression Of Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 646 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 646 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 37 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-CJ-4868-01): tumor purity 0.47, ploidy 1.94, whole-genome doublings 0 (call status: legacy_call).
